Gene-level copy-number profile of tumor specimen C3L-05781-01 from CPTAC case C3L-05781, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 61.8 years (22,556 days).
Specimen C3L-05781-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1c6215a8-2fcd-43a0-9957-c3d520f20ac8.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-05781-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,729 have no estimate.
https://portal.gdc.cancer.gov/files/7db1d793-0619-42af-b064-f2f8ce9effc1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 589; copy number 1: 10,459; copy number 2: 44,087; copy number 3: 3,523; copy number 4: 235; copy number 5: 1.

Homozygous deletions (total copy number 0; autosomes only): 77 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,242,249–25,338,213, 6 genes (within-gene range 0–1): RSRP1, AL031432.3, AL031432.2, RHD, SDHDP6, AL928711.1.
- chr4:181,064,089–181,523,001, 4 genes: LINC00290, AC019235.1, LINC02500, AC093840.1.
- chr9:21,966,929–22,128,103, 8 genes (within-gene range 0–1): CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.
- chr9:41,979,352–42,213,918, 6 genes: CR788268.1, RN7SL343P, SPATA31A6, AL445584.1, FAM74A7, AL445584.3.
- chr9:60,914,407–61,582,675, 13 genes: SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3, SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3.
- chr10:46,369,113–46,537,864, 7 genes: FAM25BP, AC244230.1, ANXA8L1, AC244230.2, LINC00842, HNRNPA1P33, NPY4R.
- chr10:79,703,227–79,714,681, 1 gene (within-gene range 0–1): NUTM2B.
- chr15:30,282,533–30,614,561, 23 genes: AC135731.2, AC019322.4, Y_RNA, CHRFAM7A, AC019322.1, U8, AC019322.3, GOLGA8R, RN7SL196P, AC019322.2, AC127502.1, AC127502.2, AC127502.3, AC026150.2, AC026150.1, GOLGA8Q, RN7SL796P, DNM1P50, ULK4P2, U8, GOLGA8H, AC026150.3, RN7SL628P.
- chr15:34,382,069–34,588,503, 9 genes (within-gene range 0–1): MIR1233-1, AC025678.2, AC025678.3, HNRNPLP2, FSCN1P1, DNM1P5, GOLGA8B, MIR1233-2, AC027139.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:70,837,738–70,838,013, 1 gene, copy number 5: AC073873.1.

Autosomal genes at a single copy (total copy number 1): 8,115. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
